Somatic mutation profile of tumor specimen TCGA-CV-5978-01A (aliquot TCGA-CV-5978-01A-11D-1683-08) from TCGA case TCGA-CV-5978, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 53.3 years (19,480 days).
Specimen TCGA-CV-5978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a71ca9e3-3d59-486a-84bd-de21249ef8a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5978-11A (Solid Tissue Normal), aliquot TCGA-CV-5978-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f7298bf-04ef-4803-826b-8a45cd64a247

The open-access MAF lists 185 somatic variants for this specimen: 141 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 39, Nonsense Mutation 14, Splice Site 6, Frame Shift Del 3, Splice Region 3, RNA 3, In Frame Del 2, Frame Shift Ins 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs1554160638, CM060367, COSV104389441, COSV99222117; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691043, CM115637, COSV52672812, COSV52700410; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101352237; called by muse, mutect2, varscan2
- ACKR1 | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.893); catalogued as COSV100929435, COSV100929591; called by muse, mutect2
- ADAMTS7 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs778559290, COSV101182989, COSV66306530; called by muse, mutect2, varscan2
- ALX1 | c.532-1G>C p.X178_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100374245; called by muse, mutect2, varscan2
- AMER3 | c.2317C>A p.Q773K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV100365865; called by mutect2, varscan2
- ASXL1 | c.4171A>T p.S1391C | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100037303; called by muse, mutect2, varscan2
- ASXL3 | c.3166G>T p.D1056Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99322806; called by muse, mutect2, varscan2
- ATF7IP | c.2548G>A p.V850M | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as COSV99661046; called by muse, mutect2, varscan2
- ATRX | c.2498C>A p.A833D | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.102); catalogued as COSV100969810; called by muse, mutect2, varscan2
- BCOR | c.4879G>T p.D1627Y (on ENST00000378444 / NM_001123385.2; = p.D1593Y on NM_017745.6) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100652715; called by muse, mutect2, varscan2
- BCOR | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100652718; called by muse, mutect2
- BRINP3 | c.1536del p.I513Ffs*25 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | catalogued as COSV66519069; called by mutect2, pindel, varscan2
- C3 | c.1845+2T>A p.X615_splice | Splice Site (SNP) | VAF 18/222 reads (8%) | catalogued as COSV55568162, COSV55576867, COSV99835816; called by muse, mutect2
- CAPN9 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99679794; called by muse, mutect2, varscan2
- CD163 | c.1099+1G>C p.X367_splice | Splice Site (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100775570; called by muse, mutect2, varscan2
- CDH12 | c.2051T>C p.I684T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV101200669; called by muse, mutect2, varscan2
- CDH18 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56927210, COSV99931214; called by muse, mutect2, varscan2
- CDH8 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100178933, COSV54872005; called by muse, mutect2, varscan2
- CDKL5 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV101183971, COSV66110537; called by muse, mutect2, varscan2
- CLCN4 | c.2191G>T p.G731W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151016, COSV101073592; called by muse, mutect2, varscan2
- CLCN5 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.074); catalogued as COSV100259702; called by muse, mutect2, varscan2
- CLIP3 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV100859223; called by muse, mutect2, varscan2
- COG5 | c.1686G>A p.K562= | Splice Region (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99771071; called by muse, mutect2
- COL25A1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV101211019; called by muse, mutect2, varscan2
- COL5A1 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100879311; called by muse, mutect2, varscan2
- COL6A1 | c.2657C>A p.P886Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as COSV100719818; called by muse, mutect2, varscan2
- COL6A6 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100649645; called by muse, mutect2, varscan2
- CPNE2 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99321130; called by muse, mutect2
- CRTC3 | c.1710G>T p.E570D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.992); catalogued as COSV99185601; called by muse, mutect2
- CSMD3 | c.3801C>A p.C1267* (on ENST00000297405 / NM_001363185.1; = p.C1163* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99820861; called by muse, mutect2, varscan2
- CTNND2 | c.3177C>G p.I1059M | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.387); catalogued as COSV100470157; called by muse, mutect2, varscan2
- CTNND2 | c.2381T>G p.L794R | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV100470159; called by muse, varscan2
- CTNND2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV58868041; called by muse, mutect2, varscan2
- DLC1 | c.4496C>A p.S1499Y (on ENST00000276297 / NM_001348081.2; = p.S1062Y on NM_006094.5) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); catalogued as COSV99360329; called by muse, mutect2, varscan2
- DLG2 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711873, COSV99713487; called by muse, mutect2, varscan2
- DMD | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs751164104, COSV55862666; called by muse, mutect2, varscan2
- DNAH11 | c.4928G>A p.G1643E | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1562720517, COSV100176173, COSV100180820; called by muse, mutect2, varscan2
- DNAH5 | c.12703A>C p.K4235Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV99443450; called by muse, mutect2
- DNAH5 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1022453162, COSV99443459; called by muse, mutect2, varscan2
- DNM3 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV100797711; called by muse, mutect2, varscan2
- DSCAM | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV68023120; called by muse, mutect2, varscan2
- ENPP2 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV99307212; called by muse, mutect2, varscan2
- EPHA4 | c.1127A>T p.K376M | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as COSV99915180; called by muse, mutect2, varscan2
- EXOC3L4 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs750552954, COSV101197535; called by muse, mutect2, varscan2
- FAM135B | c.1874A>T p.E625V | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV99417266; called by muse, mutect2
- FAM207A | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs1191873437, COSV99384175; called by muse, mutect2, varscan2
- FGD1 | c.2596C>G p.R866G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as COSV100910727, COSV64309537; called by muse, mutect2, varscan2
- FGD1 | c.1677T>A p.N559K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100910729, COSV100910916; called by muse, mutect2
- FIBCD1 | c.713-2A>T p.X238_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as rs1182361744, COSV99446526; called by muse, mutect2, varscan2
- FUT9 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV100132812, COSV100134133; called by muse, mutect2, varscan2
- G2E3 | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV99249219; called by muse, mutect2, varscan2
- GALNT16 | c.1241G>A p.W414* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100545636, COSV100545638; called by muse, mutect2, varscan2
- GGA1 | c.306T>C p.Y102= | Splice Region (SNP) | VAF 55/159 reads (35%) | catalogued as COSV100289608; called by muse, mutect2, varscan2
- GLA | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1386622522, COSV99516113; called by muse, mutect2, varscan2
- GLYATL1 | c.148C>A p.P50T (on ENST00000317391 / NM_001354699.1; = p.P81T on NM_080661.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100265066; called by muse, mutect2, varscan2
- GMPS | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99902802; called by muse, mutect2, varscan2
- GPR101 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs143030995, COSV53238063; called by muse, mutect2, varscan2
- GRID1 | c.1949C>A p.A650D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100021119; called by muse, mutect2, varscan2
- GRIK2 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.917); catalogued as COSV100021887; called by muse, mutect2, varscan2
- GYPC | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99391531; called by muse, mutect2, varscan2
- H3C10 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV60799422; called by muse, mutect2, varscan2
- HPSE2 | c.449A>T p.D150V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs1205743087, COSV100984609; called by muse, mutect2, varscan2
- INPP4B | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99522688; called by muse, mutect2
- KCNB2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs770305852, COSV73050540; called by muse, mutect2, varscan2
- KEAP1 | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99407169; called by muse, mutect2, varscan2
- KIF27 | c.1612del p.I538* | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV99927144; called by mutect2, pindel
- LETM2 | c.1162A>T p.T388S (on ENST00000379957 / NM_001286819.2; = p.T293S on NM_144652.3) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99907199; called by muse, mutect2, varscan2
- LRP1B | c.10021G>T p.D3341Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67269553; called by muse, mutect2, varscan2
- LRRK2 | c.6095C>G p.S2032* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100108703; called by muse, mutect2, varscan2
- MC5R | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100228873; called by muse, mutect2, varscan2
- MFSD2B | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs1446495831; called by muse, mutect2
- MINDY1 | c.315G>C p.R105S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100385200; called by muse, mutect2
- MORC1 | c.2570A>T p.Q857L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99224760; called by muse, mutect2, varscan2
- MRGPRX3 | c.737G>C p.W246S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101283463; called by muse, mutect2
- MSR1 | c.1077C>A p.H359Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100026278, COSV50506936; called by muse, mutect2, varscan2
- MUC16 | c.28370A>G p.H9457R | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as COSV101197390; called by muse, mutect2, varscan2
- MUC16 | c.24472G>T p.V8158F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV101197391; called by muse, mutect2, varscan2
- MYH15 | c.1223T>A p.V408E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99841916; called by muse, mutect2, varscan2
- MYO16 | c.3898C>A p.P1300T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100694993; called by muse, mutect2, varscan2
- MYORG | c.2087T>G p.L696R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.801); catalogued as COSV99898242; called by muse, mutect2, varscan2
- NAA10 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV100603722; called by muse, mutect2
- NAALADL2 | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.916); catalogued as COSV101379819; called by muse, mutect2
- NLRP6 | c.2352G>C p.Q784H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs779068594, COSV100380896, COSV56460662; called by muse, mutect2, varscan2
- NOX4 | c.846+1G>T p.X282_splice | Splice Site (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99629209; called by muse, varscan2
- NRK | c.1452G>T p.Q484H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV99078908, COSV99686264; called by muse, mutect2, varscan2
- NTRK3 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100712045; called by muse, mutect2, varscan2
- NXPH4 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100197375, COSV61074664; called by muse, mutect2, varscan2
- OR2W3 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100831567; called by muse, mutect2
- OR5F1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99558301; called by muse, mutect2, varscan2
- OR6B1 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV101281625; called by muse, mutect2, varscan2
- PAPPA2 | c.3932T>C p.L1311P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62799474; called by muse, mutect2
- PCDH10 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV99992625; called by muse, mutect2, varscan2
- PCDHB10 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99503500; called by muse, mutect2, varscan2
- PCDHGB3 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV53976311, COSV99528387; called by muse, mutect2, varscan2
- PHKA2 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV101176550; called by muse, mutect2, varscan2
- PLS3 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99171594; called by muse, mutect2
- PLSCR2 | c.434C>A p.S145Y (on ENST00000497985 / NM_001199978.1; = p.S72Y on NM_020359.2) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100367546, COSV60865530; called by muse, mutect2, varscan2
- PORCN | c.1012G>A p.A338T (on ENST00000326194 / NM_203475.3; = p.A327T on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs782558992, COSV100400244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R3B | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100133867; called by muse, mutect2, varscan2
- PTCHD3 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as COSV101438794; called by muse, mutect2, varscan2
- RB1CC1 | c.1918A>T p.K640* | Nonsense Mutation (SNP) | VAF 33/123 reads (27%) | catalogued as COSV99205007; called by muse, mutect2, varscan2
- RGS18 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV100817631, COSV66507894; called by muse, mutect2, varscan2
- RIMS1 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99322933; called by muse, mutect2, varscan2
- RPE65 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1395763356, COSV99253481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.4438T>C p.L1480= (on ENST00000333535 / NM_198056.3; = p.L1479= on NM_000335.5) | Splice Region (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100345846, COSV100346329, COSV61141698; called by muse, mutect2, varscan2
- SEL1L2 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99532368; called by muse, mutect2, varscan2
- SLC25A14 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99502254; called by muse, mutect2
- SLC7A14 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | catalogued as rs1316436990, COSV99200278; called by muse, mutect2
- SMC4 | c.2988A>C p.E996D | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV100557388; called by muse, mutect2, varscan2
- SRGAP2 | c.2525C>T p.S842F (on ENST00000624873 / NM_001170637.4; = p.S843F on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99832205; called by muse, mutect2, varscan2
- SRRM3 | c.1685A>G p.K562R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV100418532; called by muse, mutect2
- ST8SIA5 | c.538A>T p.R180W | Missense Mutation (SNP) | VAF 7/70 reads (10%) | PolyPhen possibly damaging (0.796); catalogued as COSV100164439; called by muse, mutect2
- SYT10 | c.1401C>A p.C467* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as COSV104391155, COSV99950814; called by muse, mutect2, varscan2
- TACR1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs138993766; called by muse, mutect2, varscan2
- TBL1X | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99028550, COSV99481949; called by muse, mutect2, varscan2
- TEX15 | c.1499A>G p.Y500C (on ENST00000256246; = p.Y883C on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99820549; called by muse, mutect2, varscan2
- TFCP2L1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.119); catalogued as rs1391301751, COSV55290214; called by muse, mutect2, varscan2
- TGM4 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV99942078; called by muse, mutect2, varscan2
- TKTL2 | c.517C>G p.H173D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV54920579, COSV99760976, COSV99761379; called by muse, mutect2, varscan2
- TRPC3 | c.1249C>T p.Q417* (on ENST00000379645 / NM_001366479.2; = p.Q344* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99311893; called by muse, mutect2, varscan2
- TYW3 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558428; called by muse, mutect2
- USP38 | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189018; called by muse, mutect2, varscan2
- WNT8B | c.189G>C p.W63C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100648914; called by muse, mutect2, varscan2
- ZBTB24 | c.1614G>T p.Q538H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV100018250; called by muse, mutect2, varscan2
- ZNF264 | c.1430A>T p.H477L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99567054; called by muse, mutect2, varscan2
- ZNF318 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1367533696, COSV100545867; called by muse, mutect2, varscan2
- ZNF536 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1431241819, COSV62819204; called by muse, mutect2, varscan2
- ZSCAN10 | c.1432C>T p.R478C (on ENST00000252463; = p.R533C on NM_032805.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99373748; called by muse, mutect2
- ZWILCH | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1464677452, COSV100328339; called by muse, mutect2, varscan2
- CLDND2 | c.103_105del p.Q35del | In Frame Del (DEL) | VAF 14/64 reads (22%) | called by pindel, varscan2
- CUX1 | c.516dup p.A173Cfs*22 (on ENST00000292535 / NM_181552.4; = p.A184Cfs*22 on NM_001913.5) | Frame Shift Ins (INS) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.2194G>T p.V732F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- IGKV3D-11 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IP6K2 | c.1005dup p.D336* | Frame Shift Ins (INS) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- KLHL25 | c.1437_1452del p.W482Lfs*38 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- NBPF11 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.745); called by mutect2, varscan2
- NFE2L2 | c.93_113del p.V32_D38del | In Frame Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- NVL | c.155_184+7delinsAATGCTTTTAGGATTCAGGTAGAAAAAGGTGAGTCTT p.X52_splice | Splice Site (ONP) | VAF 9/61 reads (15%) | called by mutect2*, pindel, varscan2*
- ZNF836 | c.101G>T p.W34L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGAP6 | c.69G>T p.S23= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs782058724, COSV100929012; called by muse, mutect2, varscan2
- ANKRD27 | c.951A>G p.L317= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs756246697, COSV100042471; called by muse, mutect2
- ATG2B | c.1491A>G p.S497= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100737616; called by muse, mutect2, varscan2
- ATP1A4 | c.279C>A p.T93= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV100927425; called by muse, varscan2
- CR2 | c.1689A>G p.G563= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100889498; called by muse, mutect2, varscan2
- CSMD1 | c.8343C>T p.S2781= (on ENST00000520002; = p.S2780= on NM_033225.6) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100141902; called by muse, mutect2, varscan2
- CSMD3 | c.3909G>A p.T1303= (on ENST00000297405 / NM_001363185.1; = p.T1199= on NM_052900.3) | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs200793759, COSV52161031; called by muse, mutect2, varscan2
- DACT1 | c.330G>T p.L110= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100241497; called by muse, mutect2, varscan2
- DHRS7C | c.855C>T p.Y285= (on ENST00000330255 / NM_001220493.2; = p.Y284= on NM_001105571.3) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1296866792, COSV57653345; called by muse, mutect2
- DNAH5 | c.8589G>A p.V2863= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as rs760542094, COSV99443455; called by muse, mutect2, varscan2
- DNAH5 | c.2910T>G p.L970= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV99443462; called by muse, mutect2, varscan2
- DVL1 | c.1392G>T p.R464= (on ENST00000378888 / NM_001330311.2; = p.R439= on NM_004421.3) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100229172; called by muse, mutect2, varscan2
- DZANK1 | c.1527G>A p.R509= (on ENST00000262547 / NM_001099407.1; = p.R316= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99361417; called by muse, mutect2, varscan2
- FAM47A | c.348G>T p.A116= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100649654, COSV60495620; called by muse, mutect2, varscan2
- GYPC | c.81C>A p.T27= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99391527; called by muse, mutect2, varscan2
- HUWE1 | c.3933C>T p.S1311= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV99470155; called by muse, mutect2, varscan2
- IGKV1D-16 | c.84G>A p.Q28= | Silent (SNP) | VAF 64/210 reads (30%) | called by muse, varscan2
- ISCU | c.264T>C p.A88= (on ENST00000311893 / NM_213595.4; = p.A63= on NM_014301.4) | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99933774; called by muse, mutect2
- IWS1 | c.657T>C p.P219= | Silent (SNP) | VAF 32/240 reads (13%) | catalogued as COSV99766928; called by muse, mutect2, varscan2
- KIAA1109 | c.11085G>C p.V3695= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99145346; called by muse, mutect2, varscan2
- LRFN3 | c.316C>T p.L106= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99873055; called by muse, mutect2, varscan2
- ODF1 | c.189C>G p.R63= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as COSV99573906; called by muse, mutect2, varscan2
- OR10A3 | c.861G>A p.P287= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs200152269; called by muse, mutect2, varscan2
- OR2T35 | c.714T>C p.F238= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100442110; called by muse, mutect2, varscan2
- OR9G4 | c.483C>T p.A161= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV100264949; called by muse, mutect2, varscan2
- PDZD3 | c.1092G>T p.L364= (on ENST00000531114; = p.L284= on NM_024791.4) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99423491; called by muse, mutect2, varscan2
- PFKFB1 | c.415C>A p.R139= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV100895553, COSV66628063; called by muse, mutect2, varscan2
- PLEKHA5 | c.2011C>T p.L671= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100163248; called by muse, mutect2, varscan2
- RIT2 | c.486C>A p.T162= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs1170217010, COSV100449498; called by muse, mutect2, varscan2
- SLC4A3 | c.2259C>G p.L753= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV56093694, COSV99812243; called by muse, mutect2, varscan2
- SLC8A3 | c.1521C>A p.P507= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs890730314, COSV100775808; called by muse, mutect2, varscan2
- SNRPC | c.453G>A p.R151= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99765121; called by muse, mutect2, varscan2
- SRGAP3 | c.2949G>T p.T983= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100840620; called by muse, mutect2, varscan2
- TGFBR1 | c.1095T>C p.I365= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100895238; called by muse, mutect2, varscan2
- TMEM225 | c.582A>G p.P194= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100902719; called by muse, mutect2, varscan2
- TRBV27 | c.132G>A p.Q44= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- WDR17 | c.2193A>G p.E731= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99706504; called by muse, mutect2, varscan2
- ZIC4 | c.627G>T p.P209= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs767781944, COSV67171279, COSV67172310; called by muse, mutect2, varscan2
- ZNF519 | c.333A>G p.K111= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1213549593, COSV101645545; called by muse, mutect2, varscan2
- AP000769.3 | n.15G>A | RNA (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- AP3D1 | c.2602-1067G>A | Intron (SNP) | VAF 8/49 reads (16%) | catalogued as rs200212737, COSV100642354; called by muse, mutect2, varscan2
- EI24P4 | n.833C>A | RNA (SNP) | VAF 42/290 reads (14%) | called by muse, mutect2, varscan2
- OR1N2 | c.-23G>A | 5'UTR (SNP) | VAF 9/81 reads (11%) | catalogued as rs141317564; called by muse, mutect2, varscan2
- SSPOP | n.14203T>C | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100946896; called by muse, mutect2
